Surgical pathology report (de-identified scan), TCGA case TCGA-86-8278, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Asterand, specimen TCGA-86-8278-01A (Primary Tumor).

[page 1 of 4]
TCGA Pathology Reports

[REDACTED]

[REDACTED] ID		Gross Description	Microscopic Description
[REDACTED]			

[page 2 of 4]
Diagnosis Details	Comments	Formatted Path Report
		LUNG TISSUE CHECKLIST Specimen type: Lobectomy Tumor site: Lung Tumor size: 3 x 2 x 2 cm Histologic type: Mucinous adenocarcinoma Histologic grade: Moderately differentiated Tumor extent: Visceral pleura Other tumor nodules: Not specified Lymph nodes: 3/3 positive for metastasis (Intrathoracical 3/3) Lymphatic invasion: Not specified Venous invasion: Not specified Margins: Not specified Evidence of neo-adjuvant treatment: Not specified Additional pathologic findings: Not specified Comments: positive for CK7, TTF1

[page 3 of 4]
OpenClinica ID	Excision date

[page 4 of 4]
Laterality

Left- lower

Source: NCI Genomic Data Commons file ca8e9d4a-3a2f-4f90-b877-b9f4252669d8 (TCGA-86-8278.75C05D77-D3B7-4CD1-9E6F-D8A18FC23F6C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).